Somatic mutation profile of tumor specimen TCGA-EJ-5525-01A (aliquot TCGA-EJ-5525-01A-01D-1576-08) from TCGA case TCGA-EJ-5525, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 67.2 years (24,535 days).
Specimen TCGA-EJ-5525-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 931a87e2-b998-4162-9d5d-c6dee6d4e9d2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-5525-10A (Blood Derived Normal), aliquot TCGA-EJ-5525-10A-01D-1577-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1ea10cb5-5c85-407f-a5af-822b2a33963b

The open-access MAF lists 61 somatic variants for this specimen: 51 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 39, Silent 10, Nonsense Mutation 6, Frame Shift Del 5, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACVRL1 | c.1232G>A p.R411Q | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs121909284, CM040665, CM960013, COSV66359807; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CTNNB1 | c.94G>C p.D32H | Missense Mutation (SNP) | VAF 22/58 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs28931588, COSV62687956, COSV62688134, COSV62688665; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 63/131 reads (48%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACBD5 | c.1348G>T p.A450S (on ENST00000375888 / NM_001352568.1; = p.A441S on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 140/341 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101022429, COSV65521536; called by muse, mutect2, varscan2
- ANK2 | c.1397C>T p.T466M | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs786205722, COSV52161357; ClinVar: uncertain significance; called by muse, mutect2
- ARID4B | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 153/183 reads (84%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as COSV51397993; called by muse, mutect2, varscan2
- CCNE2 | c.908A>C p.H303P | Missense Mutation (SNP) | VAF 102/518 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV57377677; called by muse, mutect2, varscan2
- CELSR3 | c.9232C>T p.R3078W | Missense Mutation (SNP) | VAF 73/191 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.936); catalogued as rs773449883, COSV51061393; called by muse, mutect2, varscan2
- CHAT | c.1238A>T p.Y413F | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT tolerated (0.52); PolyPhen benign (0.1); catalogued as COSV60334224; called by muse, mutect2, varscan2
- COL27A1 | c.5078T>C p.L1693P | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61931215; called by muse, mutect2, varscan2
- COQ8A | c.547C>T p.Q183* | Nonsense Mutation (SNP) | VAF 34/38 reads (89%) | catalogued as rs1433119560, COSV64659529; called by muse, mutect2, varscan2
- CRYBG1 | c.3971T>A p.L1324* | Nonsense Mutation (SNP) | VAF 18/247 reads (7%) | catalogued as COSV64814921; called by muse, mutect2
- CYP7B1 | c.203G>T p.R68M | Missense Mutation (SNP) | VAF 90/496 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.381); catalogued as rs1401046348, COSV100042497, COSV59598067; called by muse, mutect2, varscan2
- DCBLD1 | c.164C>G p.S55C | Missense Mutation (SNP) | VAF 72/185 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51646712; called by muse, mutect2, varscan2
- FGFR1OP2 | c.251A>G p.K84R | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT tolerated (0.82); PolyPhen benign (0.011); catalogued as rs1049025023, COSV57588697; called by muse, mutect2, varscan2
- GLI1 | c.2207A>T p.E736V | Missense Mutation (SNP) | VAF 77/226 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as COSV57368128; called by muse, mutect2, varscan2
- HDAC6 | c.1102C>T p.H368Y | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV61930867; called by muse, mutect2, varscan2
- IWS1 | c.617C>T p.P206L | Missense Mutation (SNP) | VAF 121/410 reads (30%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.01); catalogued as COSV54872239; called by muse, mutect2, varscan2
- KHDRBS3 | c.255G>T p.K85N | Missense Mutation (SNP) | VAF 89/482 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63424556; called by muse, mutect2, varscan2
- KHDRBS3 | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 89/485 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63421187; called by muse, mutect2, varscan2
- KIF1A | c.4822C>T p.R1608W (on ENST00000320389 / NM_001379639.1; = p.R1600W on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/279 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1372429864, COSV57503238; called by muse, mutect2, varscan2
- KRT25 | c.1197C>G p.Y399* | Nonsense Mutation (SNP) | VAF 13/344 reads (4%) | catalogued as COSV56446784; called by muse, mutect2
- LILRA4 | c.1169C>T p.A390V | Missense Mutation (SNP) | VAF 98/300 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as rs1484171073, COSV52490016; called by muse, varscan2
- MAP1S | c.680T>A p.L227Q | Missense Mutation (SNP) | VAF 41/76 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60724841; called by muse, mutect2, varscan2
- MAP7D2 | c.1568G>A p.R523H | Missense Mutation (SNP) | VAF 112/136 reads (82%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs774928077, COSV101107277, COSV65530773, COSV65530919; called by muse, varscan2
- MEF2C | c.680T>C p.V227A | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (0.96); PolyPhen probably damaging (0.966); catalogued as COSV60941044; called by muse, mutect2, varscan2
- MYCBP2 | c.7089G>A p.M2363I (on ENST00000357337; = p.M2401I on NM_015057.5) | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.48); catalogued as COSV62041402; called by muse, mutect2, varscan2
- MYH7B | c.1393G>T p.V465L | Missense Mutation (SNP) | VAF 10/210 reads (5%) | SIFT tolerated (0.53); PolyPhen benign (0.017); catalogued as COSV53426160; called by muse, mutect2
- MYO1H | c.1489G>A p.A497T | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.81); catalogued as rs967236285, COSV60451808; called by muse, mutect2, varscan2
- MYO5C | c.154G>C p.V52L | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV55912654; called by muse, mutect2, varscan2
- NAAA | c.187G>C p.A63P | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.054); catalogued as COSV54434051; called by muse, mutect2, varscan2
- NEFM | c.2600A>T p.D867V | Missense Mutation (SNP) | VAF 58/72 reads (81%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.852); catalogued as COSV55335256; called by muse, mutect2, varscan2
- OR9Q2 | c.620T>G p.M207R | Missense Mutation (SNP) | VAF 64/168 reads (38%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.48); catalogued as COSV61112866; called by muse, mutect2, varscan2
- OSBPL3 | c.1739A>G p.E580G | Missense Mutation (SNP) | VAF 70/195 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.911); catalogued as COSV57663052; called by muse, mutect2, varscan2
- PGLYRP3 | c.713G>T p.C238F | Missense Mutation (SNP) | VAF 109/616 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51953191; called by muse, mutect2, varscan2
- PIWIL1 | c.1267C>T p.R423* | Nonsense Mutation (SNP) | VAF 121/310 reads (39%) | catalogued as rs750875858, COSV55344677; called by muse, mutect2, varscan2
- PM20D1 | c.184C>A p.P62T | Missense Mutation (SNP) | VAF 71/171 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV65649771; called by muse, mutect2, varscan2
- PROZ | c.631A>C p.N211H | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.304); catalogued as COSV61440592; called by muse, mutect2
- PRSS55 | c.407T>C p.I136T | Missense Mutation (SNP) | VAF 176/245 reads (72%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.448); catalogued as rs374120510; called by muse, mutect2, varscan2
- RNF6 | c.1939C>T p.Q647* | Nonsense Mutation (SNP) | VAF 83/122 reads (68%) | catalogued as COSV60420724; called by muse, mutect2, varscan2
- SCN4A | c.102G>C p.E34D | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.403); catalogued as COSV71129391; called by muse, mutect2, varscan2
- SMAD4 | c.1512T>A p.S504R | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV61689102, COSV61689588; called by muse, mutect2
- TACR3 | c.1207G>A p.V403M | Missense Mutation (SNP) | VAF 172/424 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.248); catalogued as rs553885967, COSV59197525; called by muse, mutect2, varscan2
- TBC1D2 | c.923T>G p.V308G | Missense Mutation (SNP) | VAF 64/174 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.154); catalogued as COSV59789386; called by muse, mutect2, varscan2
- TNKS | c.2713A>T p.T905S | Missense Mutation (SNP) | VAF 66/106 reads (62%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV60067186; called by muse, mutect2, varscan2
- TP53 | c.607del p.V203Wfs*44 | Frame Shift Del (DEL) | VAF 22/40 reads (55%) | catalogued as COSV52761693, COSV52809012, COSV52965683; called by mutect2, pindel, varscan2
- UNC79 | c.1339G>T p.E447* (on ENST00000393151 / NM_001346218.2; = p.E270* on NM_020818.5) | Nonsense Mutation (SNP) | VAF 19/37 reads (51%) | catalogued as COSV56414194, COSV99828723; called by muse, mutect2, varscan2
- DNASE2B | c.136del p.Y46Ifs*16 | Frame Shift Del (DEL) | VAF 4/10 reads (40%) | called by mutect2, varscan2
- ITSN1 | c.3149del p.F1050Sfs*6 | Frame Shift Del (DEL) | VAF 65/193 reads (34%) | called by mutect2, pindel, varscan2
- NR1D2 | c.381del p.R128Gfs*14 | Frame Shift Del (DEL) | VAF 72/211 reads (34%) | called by mutect2, pindel, varscan2
- PLEKHA3 | c.342_357del p.K114Nfs*9 | Frame Shift Del (DEL) | VAF 42/124 reads (34%) | called by mutect2, pindel, varscan2
- ABCA7 | c.5029C>T p.L1677= | Silent (SNP) | VAF 37/51 reads (73%) | catalogued as COSV54038161; called by muse, mutect2, varscan2
- ACKR3 | c.771C>T p.Y257= | Silent (SNP) | VAF 223/377 reads (59%) | catalogued as rs572775769, COSV56021014; called by muse, mutect2, varscan2
- ADGRA1 | c.1603T>C p.L535= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as COSV66927775; called by muse, mutect2, varscan2
- ASB6 | c.1167G>A p.P389= | Silent (SNP) | VAF 57/133 reads (43%) | catalogued as rs200707909, COSV52965051; called by muse, mutect2, varscan2
- GTF2H1 | c.666A>G p.T222= | Silent (SNP) | VAF 57/161 reads (35%) | catalogued as COSV56379533; called by muse, mutect2, varscan2
- IRGQ | c.114C>T p.P38= | Silent (SNP) | VAF 24/76 reads (32%) | catalogued as COSV60671635; called by muse, mutect2, varscan2
- LRRC37B | c.975A>C p.T325= | Silent (SNP) | VAF 74/183 reads (40%) | catalogued as COSV58955320; called by muse, mutect2, varscan2
- TRAPPC10 | c.2157T>C p.A719= | Silent (SNP) | VAF 70/315 reads (22%) | catalogued as COSV52382035; called by muse, mutect2, varscan2
- TRPM1 | c.4431C>T p.I1477= | Silent (SNP) | VAF 15/516 reads (3%) | catalogued as COSV56643408; called by muse, mutect2
- ZIK1 | c.318C>T p.V106= | Silent (SNP) | VAF 50/136 reads (37%) | catalogued as COSV56738697; called by muse, mutect2, varscan2
